Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABR, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABR-01A (Primary Tumor).

[page 1 of 3]
Surgery date:

Surgical Pathology

DIAGNOSIS:

C. Pancreatic head, duodenum, common bile duct, Whipple resection: Invasive moderately differentiated, grade 3 (of 4) ductal adenocarcinoma is identified forming a mass (3.2 x 2.3 x 1.6 cm) located in the pancreatic head and neck. The tumor extends beyond pancreas to involve peripancreatic soft tissue. The pancreatic duct is also involved. Angiolymphatic invasion is absent. Perineural invasion is present. The portal vein groove margin is focally positive for invasive carcinoma. However, after re-excision of this area (see part D below), all surgical margins, including uncinate, common hepatic duct, and pancreatic neck (see parts A and B below), are negative for tumor. The patient has had no prior treatment. The adjacent non-neoplastic pancreatic parenchyma shows marked chronic pancreatitis. The gallbladder is unremarkable. Multiple (14) regional lymph nodes are negative for tumor. The pancreatic parenchyma is distorted with curvilinear change possibly related to preoperative abscess formation and tumor growth as it extends into peripancreatic fat.

A. Hepatic duct, common, margin, excision: Negative for tumor.

B. Pancreas, neck, margin, excision: Negative for tumor.

D. Portal vein, excision: Focally involved by grade 3 (of 4) adenocarcinoma in the mid-region of the segmentally-resected portal vein. However, the superior and inferior margins are negative for tumor.

AJCC stage (with available surgical material): pT3N0 (7th edition).

Frozen section histologic interpretation of portion of portal vein performed by:

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). A revised report will be issued to document the final interpretation after review of the Hematoxylin and Eosin (H&E) permanent sections.

ADDENDUM:

Frozen section interpretation has been confirmed by Hematoxylin and Eosin (H&E) permanent section review.

GROSS DESCRIPTION:

A. Received fresh labeled "common hepatic duct" is a 1.3 x 1.1 x 0.4 cm portion of pink mucosa with a lumen with orientation. All

ICD O-3

Adenocarcinoma, duct NOS

Site: Overlapping lesion 2
pancreas C25.8

QW 5/5/14

[page 2 of 3]
submitted en face. Grossed by

B. Received fresh labeled "pancratic neck margin" is a 2.8 x 1.4 x 0.5 cm portion of pancreas with orientation. Margin submitted. Grossed by

C. Received fresh labeled "head of pancreas, gallbladder, duodenum, common bile duct, portion jejunum" is a Whipple specimen consisting of 29.0 cm in length portion of duodenum, 6.9 x 4.2 x 3.1 cm portion of pancreas, 9.1 x 2.5 x 2.5 cm gallbladder. The pancreatic uncinata margin is inked yellow and shaved, the portal vein groove is inked black and submitted perpendicularly. There is a 3.3 x 2.3 x 1.6 cm infiltrative mass within the neck/head, abutting the portal vein groove margin. The mass extends to peripancreatic fat. A stent is present within the common bile duct. The gallbladder contains no choleliths. Surrounding the proximal duodenum and pancreatic head is extensive necrosis and exudate, which involves the pancreatic parenchyma. Peripancreatic lymph nodes and periduodenal lymph nodes are identified. Representative sections are submitted. Research tissue collected,
Grossed by

D. Received fresh labeled "portion portal vein" is a 1.4 cm in length medium caliber vein with orientation. The superior and inferior vein margins are submitted en face. The central part of the vein is focally indurated, 0.3 cm to the inferior margin.

BLOCK SUMMARY:

Part A: Common hepatic duct

1 Common hepatic duct margin

Part B: Pancreatic neck margin

1 Pancreatic neck margin

Part C: Head of pancreas, gallbladder, duodenum, common bile duct, portion jejunum, and stent

1 Portal vein margin 1

2 Portal vein margin 2

3 Uncinate margin 1

4 Uncinate margin 1

5 Uncinate margin 2

6 Uncinate margin 3

7 Tumor-peripancreatic fat

8 Tumor 1

9 Tumor 1

10 Tumor main duct

11 Tumor 2

12 Ampulla

13 Abscess

[page 3 of 3]
- 14 Abscess
- 15 Gallbladder
- 16 Periduodenal LN 1 (C1)
- 17 Periduodenal LN 2 (C2)
- 18 Peripancreatic LN 2 (C3)
- 19 Peripancreatic LN 5 (C4)
- 20 Peripancreatic 1 (C5)
- 21 Peripancreatic LNs 3 (C6)

Part D: Portion portal vein

- 1 Superior portal vein margin
- 2 Inferior portal vein margin
- 3 Portal vein mid

Criteria	W 1/27/14	Yes	No
Prior Malignancy History	Send call	☒	☒

Source: NCI Genomic Data Commons file a34045a6-63cf-4548-89b9-ebf7da843efe (TCGA-2J-AABR.178FDFAF-0AFA-4A07-9F59-5E0617DA3B7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).